Gene-level copy-number profile of tumor specimen TCGA-FD-A6TA-01A from TCGA case TCGA-FD-A6TA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 58.0 years (21,196 days).
Specimen TCGA-FD-A6TA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.c6cd0bb0-d046-4e6d-8605-8b2e350993bc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A6TA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/266e2b32-3632-4b90-b027-a4ff589e6616

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 354; copy number 1: 17,086; copy number 2: 39,412; copy number 3: 2,670; copy number 4: 52; copy number 5: 239; copy number 6: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A6TA-01A-12D-A338-01): tumor purity 0.6, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 315 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:40,056,850–45,051,652, 79 genes (broad region; genes not listed).
- chr4:176,844,493–177,301,253, 1 gene (within-gene range 0–1): AC097518.2.
- chr6:153,938,433–154,577,079, 11 genes: HMGB3P19, OPRM1, IPCEF1, AL357075.4, AL445220.1, CNKSR3, AL357075.2, AL357075.3, AL357075.1, MTRES1P1, RPS4XP8.
- chr6:167,208,631–167,826,812, 17 genes: AL353747.1, HPAT5, AL353747.3, AL353747.2, UNC93A, TTLL2, AL021331.1, TCP10L3, AL356123.1, LINC02538, AL356123.2, LINC02487, AL009178.1, LINC01558, AL009178.2, AL009178.3, AFDN-DT.
- chr6:168,999,401–169,810,102, 26 genes: AL109924.4, AL109924.3, AL109924.1, AL109924.2, AL136129.1, LINC01615, LINC02544, BX322234.1, THBS2, BX322234.2, VTA1P1, LINC02519, AL009176.1, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1.
- chr8:105,287,830–105,288,365, 1 gene: AC041039.1.
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–1): FOCAD.
- chr9:20,999,509–24,905,735, 74 genes (broad region; genes not listed).
- chr9:122,723,990–123,115,477, 19 genes: OR1L4, OR1L6, SKA2P1, OR5C1, PDCL, OR1K1, KRT18P67, RC3H2, SNORD90, ZBTB6, ZBTB26, AC007066.2, AC007066.3, RABGAP1, RNY1P15, AC007066.1, GPR21, AL365338.1, MIR600HG.
- chr9:123,111,546–123,111,643, 1 gene: MIR600.
- chr10:87,607,985–88,991,339, 30 genes (within-gene range 0–1): AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2.
- chr10:124,617,080–125,161,170, 15 genes: AC068896.1, FAM53B, AL513190.1, FAM53B-AS1, EEF1AKMT2, Y_RNA, ABRAXAS2, Y_RNA, NPM1P31, AL731577.2, ZRANB1, AL731577.1, CTBP2, AL731571.1, MIR4296.
- chr11:25,734,757–26,047,598, 3 genes: LINC02699, AC013799.1, AC024341.1.
- chr11:26,244,640–26,269,415, 1 gene: AC021698.1.
- chr13:93,309,669–93,395,855, 2 genes: AL160159.1, HNRNPA1P29.
- chr18:42,649,520–43,115,691, 2 genes: AC084335.1, RIT2.
- chr18:50,967,991–53,535,903, 18 genes (within-gene range 0–1): ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1, DCC, AC011155.1, VN1R76P.
- chr18:65,750,252–66,069,647, 4 genes: CDH7, AC023394.2, AC023394.1, PRPF19P1.
- chr18:71,519,962–72,638,521, 9 genes: LINC01541, AC090312.1, AC090312.2, LINC01899, AC027458.1, AC069114.1, AC069114.2, CBLN2, HNRNPA1P11.
- chr21:34,836,286–34,884,882, 1 gene: AP000331.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 242 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:17,705,408–22,520,058, 51 genes, copy number 5: AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1.
- chr21:25,361,821–25,431,701, 3 genes, copy number 6: RPL13AP7, AP001340.1, LINC00158.
- chr21:26,835,755–34,784,886, 188 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,721. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
